Somatic mutation profile of tumor specimen TCGA-77-7142-01A (aliquot TCGA-77-7142-01A-11D-2042-08) from TCGA case TCGA-77-7142, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.7 years (21,796 days).
Specimen TCGA-77-7142-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c41a8bfb-bb3d-4287-bcce-077edccc8cc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7142-11A (Solid Tissue Normal), aliquot TCGA-77-7142-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e075f6e-80fb-44cf-a02a-73cf6a4269d2

The open-access MAF lists 283 somatic variants for this specimen: 211 protein-altering or splice-affecting, 65 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 65, Nonsense Mutation 19, Splice Site 7, Frame Shift Del 4, RNA 3, Intron 3, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>C p.R249S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASS | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100741902; called by muse, mutect2, varscan2
- ACAD9 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100459385; called by muse, mutect2, varscan2
- ACTR8 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99213908; called by muse, mutect2, varscan2
- ADAMTS12 | c.4104G>T p.W1368C | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100711730, COSV61271087; called by muse, mutect2, varscan2
- ADAMTS20 | c.4608G>T p.M1536I | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101240465, COSV67134588; called by muse, mutect2, varscan2
- AFAP1L1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV99696168; called by muse, mutect2, varscan2
- AL133500.1 | c.1316A>T p.Y439F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.08); catalogued as COSV55744681, COSV99860499; called by muse, mutect2, varscan2
- AMY2A | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV101340682, COSV70214637; called by muse, mutect2, varscan2
- ANAPC1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as rs753241990, COSV61978702, COSV61980116; called by muse, mutect2, varscan2
- ARHGAP6 | c.1967C>A p.T656K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV100273611; called by muse, mutect2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by muse, mutect2, varscan2
- ATP1A4 | c.1048-1G>T p.X350_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100927524, COSV100927649; called by muse, mutect2, varscan2
- ATP6V1B1 | c.254G>C p.G85A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs963949766, COSV52270994; called by muse, mutect2, varscan2
- ATP8B4 | c.3361C>A p.R1121S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV99463198; called by muse, mutect2, varscan2
- BAZ1A | c.2333T>A p.L778* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100701224; called by muse, mutect2, varscan2
- BBS7 | c.823A>T p.N275Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99145130; called by muse, mutect2, varscan2
- BBS9 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763742314, COSV99626047; called by muse, mutect2, varscan2
- BLOC1S2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs752400195, COSV100559466; called by muse, mutect2, varscan2
- BRINP3 | c.2267C>A p.T756K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs141719999; called by muse, mutect2, varscan2
- BSDC1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100345146; called by muse, mutect2, varscan2
- C6orf58 | c.557G>T p.W186L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315071; called by muse, mutect2, varscan2
- CACNA2D4 | c.2548G>T p.A850S | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV99766606; called by muse, mutect2, varscan2
- CAPN12 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100185560; called by muse, mutect2, varscan2
- CCNB2 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99879192; called by muse, mutect2, varscan2
- CCR10 | c.1033C>A p.R345S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.415); catalogued as COSV99227090; called by muse, mutect2, varscan2
- CCT6B | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs1484438867, COSV100031051, COSV58490048; called by muse, mutect2, varscan2
- CDH18 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99938653; called by muse, varscan2
- CFAP44 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99870413; called by muse, mutect2, varscan2
- CFH | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as rs1354315554, CM1314325, COSV66410123; called by muse, mutect2, varscan2
- CHD4 | c.1177G>A p.E393K (on ENST00000357008 / NM_001363606.2; = p.E406K on NM_001273.5) | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs377488166, COSV58896143; called by muse, mutect2
- CHMP4C | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs142794802; called by muse, mutect2, varscan2
- CHSY3 | c.1020T>A p.H340Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100520045; called by muse, mutect2, varscan2
- CHSY3 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100520047; called by muse, mutect2, varscan2
- CLCA2 | c.2551C>A p.Q851K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100991763; called by muse, mutect2, varscan2
- CMKLR1 | c.67G>A p.D23N (on ENST00000312143 / NM_001142344.2; = p.D21N on NM_004072.3) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100379275; called by muse, mutect2
- CYBB | c.612del p.W206Gfs*8 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as COSV66085826; called by mutect2, varscan2
- CYBB | c.616del p.W206Gfs*8 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as CM960442; called by mutect2*, pindel, varscan2*
- CYLC1 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as COSV100255560; called by muse, mutect2, varscan2
- CYP2D6 | c.181-1G>C p.X61_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as rs201377835, CS952439, COSV100637392; ClinVar: likely benign; called by muse, mutect2
- DCAF12L2 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100758880; called by muse, mutect2, varscan2
- DGKK | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV101053231; called by muse, varscan2
- DNAH9 | c.6507G>C p.Q2169H | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as COSV99308403; called by muse, mutect2, varscan2
- DNAJC10 | c.849G>C p.L283F | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99899643; called by muse, mutect2, varscan2
- DTWD2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100407178; called by muse, mutect2, varscan2
- DYNC1H1 | c.9079G>A p.A3027T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV100795469; called by muse, mutect2, varscan2
- EEF1A2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99420040; called by muse, mutect2, varscan2
- EHF | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs1421011128, COSV57667909, COSV99140856; called by muse, mutect2, varscan2
- EIF2AK4 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775435; called by muse, varscan2
- ENPP2 | c.2395C>T p.R799W (on ENST00000075322 / NM_001040092.3; = p.R851W on NM_006209.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370024218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAAP24 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.915); catalogued as COSV54282305; called by muse, varscan2
- FAAP24 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV99578429; called by muse, varscan2
- FAM155A | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.242); catalogued as COSV101030648; called by muse, mutect2, varscan2
- FAM155A | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs200446308, COSV101030649; called by muse, mutect2, varscan2
- FAM163B | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV100619058; called by muse, mutect2
- FAM47C | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV100792975, COSV63728294; called by muse, mutect2
- FAT3 | c.10052G>A p.S3351N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53087871, COSV99971541; called by muse, mutect2, varscan2
- FCGBP | c.9004G>A p.V3002M | Missense Mutation (SNP) | VAF 72/868 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs761343551; called by muse, mutect2
- FREM1 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100772226; called by muse, mutect2, varscan2
- GABRA6 | c.695T>A p.V232D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195259; called by muse, mutect2, varscan2
- GAD2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV99393936; called by muse, mutect2, varscan2
- GALNT17 | c.1705C>G p.L569V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356295, COSV100356471; called by muse, mutect2, varscan2
- GAS2L2 | c.2072G>A p.S691N | Missense Mutation (SNP) | VAF 161/231 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1555598751; called by muse, mutect2, varscan2
- GAS7 | c.479G>A p.G160E (on ENST00000432992 / NM_201433.2; = p.G20E on NM_003644.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs1340992721, COSV100097167; called by muse, mutect2, varscan2
- GFI1 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV99647656; called by muse, mutect2, varscan2
- GLYR1 | c.1229A>C p.Y410S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100424581; called by muse, mutect2, varscan2
- GRIN3B | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99312958; called by muse, mutect2
- GRM3 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64481966; called by muse, mutect2, varscan2
- HNF4G | c.224C>T p.A75V (on ENST00000354370 / NM_001330561.2; = p.A122V on NM_004133.5) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs770285159, COSV62972179; called by muse, mutect2, varscan2
- HNRNPC | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.02); catalogued as COSV100193412; called by muse, mutect2, varscan2
- HOXD11 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99983401; called by muse, mutect2, varscan2
- HPCAL1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV57147810; called by muse, varscan2
- HRG | c.1183C>A p.H395N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as COSV99215107; called by muse, mutect2
- HSPA4 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772742465, COSV100507904; called by muse, mutect2, varscan2
- HYAL1 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99807930; called by muse, mutect2, varscan2
- IFT172 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99563475; called by muse, mutect2, varscan2
- IQCG | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 18/263 reads (7%) | catalogued as rs761029279, COSV99502110, COSV99502760; called by muse, mutect2
- KCNH7 | c.1895A>T p.N632I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100037974; called by muse, mutect2, varscan2
- KCNJ1 | c.826A>T p.S276C | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131499; called by muse, mutect2, varscan2
- KCNK10 | c.1418A>T p.Y473F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as COSV100069405; called by muse, mutect2, varscan2
- KEL | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100787317; called by muse, mutect2, varscan2
- KIF4B | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV101469416, COSV70529358; called by muse, mutect2, varscan2
- KMT2E | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769036930, COSV99997079; called by muse, mutect2, varscan2
- KRT75 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs370991901, COSV99359189; called by muse, mutect2, varscan2
- KRT85 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV99225739; called by muse, mutect2, varscan2
- KRTAP10-6 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs371882347, COSV100555629; called by muse, mutect2, varscan2
- L3MBTL2 | c.2048C>G p.S683W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); catalogued as COSV99346202; called by muse, mutect2, varscan2
- LMOD2 | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV101505471; called by muse, varscan2
- LRP1B | c.11178C>A p.N3726K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV101261602; called by muse, mutect2
- LRP1B | c.9724A>G p.K3242E | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101261603; called by muse, mutect2, varscan2
- LRP2 | c.3580T>A p.C1194S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790444; called by muse, mutect2, varscan2
- LRP2 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs748432854, COSV55572064, COSV99790445; called by mutect2, varscan2
- LRRC15 | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 107/583 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as COSV100752960; called by muse, mutect2, varscan2
- MAP1A | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV100289313; called by muse, mutect2, varscan2
- MAP3K2 | c.1065C>G p.N355K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100777239; called by muse, mutect2
- MC2R | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100563226; called by muse, mutect2, varscan2
- MSL3 | c.899G>T p.S300I (on ENST00000312196 / NM_078629.4; = p.S134I on NM_006800.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100385087; called by muse, mutect2, varscan2
- MTRF1L | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV100922054; called by muse, mutect2, varscan2
- MUC16 | c.1854G>T p.R618S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV101201882, COSV67504654; called by muse, mutect2, varscan2
- MXRA5 | c.1750A>T p.T584S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99479524; called by muse, mutect2, varscan2
- MYH11 | c.884T>C p.M295T | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100260407; called by muse, mutect2, varscan2
- NAP1L3 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100220717; called by muse, mutect2
- NLRP5 | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV101173892; called by muse, mutect2, varscan2
- NOD2 | c.2996G>T p.G999V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100318893, COSV56053095; called by muse, mutect2, varscan2
- NOTCH4 | c.4802A>T p.Q1601L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100901118; called by muse, mutect2, varscan2
- NRXN1 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052777, COSV58442242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP98 | c.1459+2T>C p.X487_splice | Splice Site (SNP) | VAF 7/115 reads (6%) | catalogued as COSV100263559; called by muse, mutect2
- OCA2 | c.50T>A p.V17E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs1237182917, COSV100668768; called by muse, mutect2
- OGT | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101035652; called by muse, mutect2, varscan2
- OR2T3 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1203667959, COSV100613440; called by muse, mutect2, varscan2
- OR4A15 | c.765G>C p.L255F | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs140315038, COSV59036327; called by muse, mutect2, varscan2
- OR4P4 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100111879; called by muse, mutect2, varscan2
- OR51G2 | c.889T>A p.Y297N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58995697; called by muse, mutect2, varscan2
- OR52E8 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV101191109; called by muse, mutect2, varscan2
- OR8H1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV100477381; called by muse, mutect2, varscan2
- OR8H1 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs773973921, COSV100477384, COSV57294640; called by muse, mutect2, varscan2
- OR8K5 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as COSV100537351; called by muse, varscan2
- OTOGL | c.6841G>T p.D2281Y (on ENST00000547103; = p.D2272Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087973; called by muse, mutect2, varscan2
- PCDH9 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100123932; called by muse, mutect2
- PCDHB8 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.323); catalogued as COSV99177477; called by muse, varscan2
- PCDHGB2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1025745459, COSV54064765, COSV99547928; called by muse, mutect2, varscan2
- PDE3B | c.1957-1G>T p.X653_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99962026, COSV99962797; called by muse, mutect2, varscan2
- PDZRN4 | c.1823C>A p.S608Y (on ENST00000402685 / NM_001164595.2; = p.S350Y on NM_013377.4) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100115589; called by muse, mutect2, varscan2
- PDZRN4 | c.2121C>A p.F707L (on ENST00000402685 / NM_001164595.2; = p.F449L on NM_013377.4) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100115591; called by muse, mutect2, varscan2
- PIK3R4 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs779956493, COSV100768612; called by muse, mutect2, varscan2
- PIN4 | c.257G>T p.G86V (on ENST00000664196; = p.G61V on NM_006223.4) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99512569; called by muse, mutect2, varscan2
- PKLR | c.895G>C p.A299P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100713045; called by muse, mutect2, varscan2
- PKP4 | c.1254G>T p.R418S | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV101081655; called by muse, mutect2, varscan2
- PNMA8A | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs367554609; called by muse, mutect2, varscan2
- POLR1A | c.3714G>T p.E1238D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV99808521; called by muse, mutect2, varscan2
- POU4F2 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV99850860; called by muse, mutect2, varscan2
- PPP4R4 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100429066; called by muse, mutect2, varscan2
- PRDM9 | c.882+1G>T p.X294_splice | Splice Site (SNP) | VAF 68/134 reads (51%) | catalogued as COSV57008561; called by muse, mutect2, varscan2
- PTPRC | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100723239; called by muse, mutect2, varscan2
- QSER1 | c.4638G>T p.K1546N (on ENST00000399302; = p.K1675N on NM_001076786.3) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101234977; called by muse, mutect2, varscan2
- QSER1 | c.4639G>T p.E1547* (on ENST00000399302; = p.E1676* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV101234978; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99921848; called by muse, mutect2, varscan2
- RABGAP1 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs367858502; called by mutect2, varscan2
- RANBP17 | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101206205, COSV101206400; called by muse, mutect2, varscan2
- RASA1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99170983; called by muse, mutect2
- RASAL1 | c.2223G>T p.R741S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV99922160; called by muse, mutect2, varscan2
- RASAL1 | c.2223-1G>T p.X741_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99922161; called by muse, mutect2, varscan2
- RBSN | c.683G>C p.R228P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99515563; called by muse, mutect2, varscan2
- REG1A | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV99287000; called by muse, mutect2, varscan2
- RFPL2 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as COSV50711612, COSV99964659; called by muse, mutect2
- RGS16 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs1480790468, COSV100842507; called by muse, mutect2, varscan2
- RGS21 | c.255+2T>C p.X85_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV101314097; called by muse, mutect2, varscan2
- RMND1 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.065); catalogued as COSV100323819; called by muse, mutect2, varscan2
- RXFP2 | c.1904C>A p.A635D | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV53636214; called by muse, mutect2, varscan2
- RYR2 | c.5076G>T p.K1692N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100773143; called by muse, mutect2, varscan2
- S1PR4 | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99859454; called by muse, mutect2, varscan2
- SATL1 | c.78G>T p.M26I (on ENST00000395409; = p.M213I on NM_001012980.2) | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100261118; called by muse, mutect2, varscan2
- SCARF2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1452511977, COSV99839486; called by muse, mutect2, varscan2
- SCGN | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs753222150, COSV100618874, COSV58544796; called by muse, mutect2, varscan2
- SCN4A | c.2708C>G p.P903R | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV101438684; called by muse, mutect2, varscan2
- SEC24C | c.2862G>T p.L954F | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100227181; called by muse, mutect2
- SEMA4F | c.2057G>T p.R686L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774869919, COSV100336167, COSV60285465; called by muse, mutect2, varscan2
- SENP7 | c.318G>T p.W106C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100053961; called by muse, mutect2, varscan2
- SH3PXD2A | c.1940G>T p.S647I (on ENST00000369774 / NM_001365079.1; = p.S619I on NM_014631.2) | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.121); catalogued as COSV100280551; called by muse, mutect2, varscan2
- SHROOM2 | c.4062C>A p.D1354E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV101099096; called by muse, mutect2, varscan2
- SIRT6 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as rs200117989, COSV100511452; called by muse, mutect2, varscan2
- SLC17A8 | c.1418G>T p.R473M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100035902; called by muse, mutect2, varscan2
- SLC17A8 | c.1419G>T p.R473S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100035904, COSV60121700; called by muse, mutect2, varscan2
- SLC17A8 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100035906, COSV60122024; called by muse, mutect2, varscan2
- SLC2A13 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99787242; called by muse, mutect2
- SLITRK5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV100281263; called by muse, varscan2
- SMCO3 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 98/179 reads (55%) | catalogued as COSV99660924; called by muse, mutect2, varscan2
- SOX5 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV100508418; called by muse, mutect2
- SOX6 | c.1252G>T p.D418Y (on ENST00000528429 / NM_001145819.2; = p.D377Y on NM_017508.3) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100322870, COSV100323368; called by muse, mutect2, varscan2
- SPNS2 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100223867, COSV61229981; called by muse, mutect2, varscan2
- TARBP1 | c.4552C>G p.L1518V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as rs1447490235, COSV50184638; called by muse, mutect2, varscan2
- TEC | c.1822G>T p.G608* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99972908; called by muse, mutect2, varscan2
- TENM3 | c.2117C>A p.A706D | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101305495; called by muse, mutect2, varscan2
- TEX47 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99787401; called by muse, mutect2, varscan2
- TKT | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as COSV56244615; called by muse, mutect2, varscan2
- TLL1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99289306; called by muse, mutect2, varscan2
- TMEM145 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs111303064, COSV99239372; called by muse, mutect2, varscan2
- TMEM202 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | catalogued as COSV100499281; called by muse, mutect2
- TMEM225 | c.541T>A p.C181S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV66693007; called by muse, mutect2
- TNIK | c.3193G>C p.E1065Q | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99459820; called by muse, mutect2
- TPH2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422414; called by muse, mutect2, varscan2
- TRIM42 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99648890; called by muse, mutect2, varscan2
- TRPS1 | c.1103C>T p.S368F (on ENST00000220888 / NM_001330599.2; = p.S381F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV55246882; called by muse, mutect2, varscan2
- TRRAP | c.3262G>T p.D1088Y | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100723072, COSV62842541; called by muse, mutect2, varscan2
- TTBK1 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.028); catalogued as rs763794735, COSV52496292, COSV99445673; called by muse, mutect2, varscan2
- TTN | c.73201A>G p.K24401E (on ENST00000591111; = p.K16977E on NM_003319.4) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV100632439; called by muse, mutect2, varscan2
- UFL1 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990151; called by muse, mutect2, varscan2
- ULK4 | c.2733T>A p.F911L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100095463, COSV57205498; called by muse, mutect2, varscan2
- USP25 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99584663; called by muse, mutect2, varscan2
- USP29 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs779038356, COSV54139634, COSV99518756; called by muse, mutect2, varscan2
- VCPIP1 | c.3461A>C p.Q1154P | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV100125804; called by muse, mutect2, varscan2
- VPS13D | c.6880G>A p.V2294I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99169682; called by muse, mutect2, varscan2
- VSX1 | c.865G>C p.A289P | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as COSV100942228; called by muse, mutect2, varscan2
- WDR25 | c.561A>T p.L187F | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100092350; called by muse, mutect2, varscan2
- WWC3 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV66502079; called by muse, mutect2, varscan2
- XAB2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs573591781, COSV99352099; called by muse, mutect2, varscan2
- ZBED1 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139808300, COSV100586112; called by muse, mutect2, varscan2
- ZCCHC14 | c.1169C>T p.S390L (on ENST00000268616; = p.S527L on NM_015144.3) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs752742696, COSV99234613; called by muse, mutect2, varscan2
- ZFAND4 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV100763128, COSV60861374; called by muse, mutect2, varscan2
- ZFPM2 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV101023631; called by muse, mutect2, varscan2
- ZNF254 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.066); catalogued as COSV100741799; called by muse, mutect2
- ZNF768 | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100776370; called by muse, mutect2, varscan2
- ZNF80 | c.168C>G p.S56R | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100352169, COSV57360690; called by muse, mutect2, varscan2
- ZNF831 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV100926289, COSV104427071; called by muse, mutect2
- ZNF862 | c.2884G>T p.A962S | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV99783870; called by muse, mutect2, varscan2
- CYP2A6 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- IGHV4-61 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- IGKV2-24 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- KDM2A | c.3045_3054del p.D1016Ffs*23 | Frame Shift Del (DEL) | VAF 33/140 reads (24%) | called by mutect2, pindel, varscan2
- KRTAP5-5 | c.103T>C p.C35R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | PolyPhen possibly damaging (0.902); called by muse, varscan2
- OR13C8 | c.713_734del p.F238* | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel
- ABCC9 | c.354G>A p.S118= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs189582135, COSV53971784; called by muse, mutect2, varscan2
- ACTA1 | c.424C>T p.L142= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100796800; called by muse, varscan2
- AIMP1 | c.627A>G p.L209= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100786221; called by muse, mutect2, varscan2
- BDP1 | c.7008A>T p.P2336= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100703594; called by muse, mutect2, varscan2
- CCDC106 | c.636C>T p.T212= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100454505; called by muse, mutect2, varscan2
- CHD6 | c.7521A>G p.T2507= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100951390; called by muse, mutect2, varscan2
- CUBN | c.4959G>T p.A1653= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV100913637, COSV64716458; called by muse, mutect2, varscan2
- CYB5R4 | c.1565A>G p.*522= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100859760; called by muse, mutect2
- DDX18 | c.108G>A p.S36= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs765795839, COSV54307134; called by muse, mutect2, varscan2
- DLD | c.1458A>G p.A486= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV99227588; called by muse, mutect2, varscan2
- DTWD2 | c.672G>A p.L224= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100407179, COSV58367172; called by muse, mutect2, varscan2
- EFHB | c.2436G>A p.E812= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV99860299; called by muse, mutect2, varscan2
- ENDOG | c.579C>T p.V193= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100778272; called by muse, mutect2, varscan2
- ERN1 | c.702G>A p.R234= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV101458585; called by muse, mutect2, varscan2
- FUT9 | c.174T>A p.T58= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100134540; called by muse, mutect2, varscan2
- GLB1L2 | c.1671C>T p.I557= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV100335519; called by muse, mutect2
- GNPTAB | c.1551G>A p.K517= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV100172459; called by muse, mutect2, varscan2
- GPR156 | c.1041G>A p.E347= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100251749; called by muse, mutect2, varscan2
- GRID2 | c.279G>T p.L93= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99947423; called by muse, mutect2, varscan2
- GRIN2B | c.3798G>T p.P1266= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV101663203; called by muse, mutect2, varscan2
- GRIP2 | c.939G>T p.L313= (on ENST00000619221; = p.L216= on NM_001080423.4) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99817734; called by muse, mutect2, varscan2
- GZF1 | c.267A>G p.S89= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs764171758, COSV100582688; called by muse, mutect2, varscan2
- HKDC1 | c.2739A>T p.A913= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100664797; called by muse, mutect2, varscan2
- HTR1E | c.658C>A p.R220= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs778639081, COSV100541346, COSV59507202; called by muse, mutect2
- IGF2 | c.225C>T p.A75= (on ENST00000434045 / NM_001127598.3; = p.A19= on NM_000612.6) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100324270; called by muse, mutect2, varscan2
- INPP4B | c.858T>A p.L286= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99527086; called by muse, mutect2, varscan2
- KANK3 | c.1923G>A p.L641= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100445214; called by muse, mutect2, varscan2
- MAGEB6B | c.348T>C p.D116= | Silent (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- MALL | c.141C>G p.A47= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV99732303; called by muse, mutect2, varscan2
- MUC17 | c.5514T>C p.P1838= | Silent (SNP) | VAF 73/437 reads (17%) | catalogued as rs146261861; called by muse, mutect2, varscan2
- MYO16 | c.1056C>T p.A352= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99193575; called by muse, mutect2, varscan2
- NTRK2 | c.2175C>T p.I725= (on ENST00000323115 / NM_001369534.1; = p.I741= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/147 reads (56%) | catalogued as rs1183251155, COSV99458885; called by muse, mutect2, varscan2
- OBSL1 | c.4188G>A p.G1396= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99523255; called by muse, mutect2, varscan2
- ODF1 | c.342A>G p.R114= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99574433; called by muse, mutect2, varscan2
- OR10G9 | c.717C>A p.T239= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100901783; called by muse, mutect2, varscan2
- OR10K2 | c.666C>G p.L222= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs752032787, COSV100149677; called by muse, mutect2, varscan2
- OR52N5 | c.690C>T p.I230= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1441705998, COSV100399785; called by muse, mutect2
- OR5A1 | c.738G>T p.S246= | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as COSV100118487; called by muse, mutect2, varscan2
- OR9K2 | c.846T>C p.F282= (on ENST00000305377; = p.F260= on NM_001005243.1) | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as rs1432912806, COSV100543941, COSV59533365; called by muse, mutect2, varscan2
- PPM1D | c.1383C>T p.V461= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100011205; called by muse, mutect2, varscan2
- RBM45 | c.241A>C p.R81= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV99618050; called by muse, mutect2, varscan2
- RPS6KC1 | c.2880C>T p.S960= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs762478973, COSV100874112; called by muse, mutect2, varscan2
- SIRPB1 | c.345C>T p.A115= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as rs752258051, COSV53539555, COSV99498578; called by muse, mutect2, varscan2
- SLC12A6 | c.1458G>T p.T486= (on ENST00000354181 / NM_001365088.1; = p.T435= on NM_005135.2) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99273508; called by muse, mutect2, varscan2
- SLC39A12 | c.720C>A p.S240= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV101070191; called by muse, mutect2, varscan2
- SLC4A10 | c.1788C>T p.S596= (on ENST00000446997 / NM_001354461.2; = p.S566= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 61/144 reads (42%) | catalogued as COSV99766040; called by muse, mutect2, varscan2
- STRA8 | c.453C>T p.L151= (on ENST00000275764; = p.L129= on NM_182489.2) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99312681; called by muse, mutect2, varscan2
- SVIL | c.5361C>T p.F1787= (on ENST00000355867 / NM_021738.3; = p.F1361= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV100881572; called by muse, mutect2
- TIMMDC1 | c.378T>C p.A126= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs376952884; called by muse, mutect2, varscan2
- TLR8 | c.2451G>A p.L817= (on ENST00000218032 / NM_138636.5; = p.L835= on NM_016610.4) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99487343; called by muse, mutect2, varscan2
- TMEM8B | c.516C>T p.N172= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs760215102, COSV100941746; called by muse, varscan2
- TRAJ35 | c.61C>T p.*21= | Silent (SNP) | VAF 31/262 reads (12%) | catalogued as rs1350101468; called by muse, mutect2, varscan2
- TRAPPC8 | c.1101A>T p.T367= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99352056; called by muse, mutect2
- TRPC1 | c.756G>T p.V252= (on ENST00000476941 / NM_001251845.2; = p.V218= on NM_003304.4) | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99859394; called by muse, mutect2
- TSPYL6 | c.180G>A p.A60= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as rs570502084, COSV57819195; called by muse, mutect2, varscan2
- TTN | c.40884A>G p.A13628= (on ENST00000591111; = p.A6204= on NM_003319.4) | Silent (SNP) | VAF 27/233 reads (12%) | catalogued as COSV100632441; called by muse, mutect2, varscan2
- UBA6 | c.534C>T p.C178= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100451577; called by muse, mutect2, varscan2
- UGT2B7 | c.570T>C p.P190= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100535338; called by muse, mutect2, varscan2
- ULK3 | c.291C>T p.G97= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs368533374; called by muse, mutect2, varscan2
- UPK3A | c.630C>T p.V210= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1257513848, COSV99343232; called by muse, mutect2, varscan2
- USH2A | c.456A>G p.V152= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100243230; called by muse, mutect2, varscan2
- ZBTB20 | c.1878G>A p.V626= (on ENST00000474710 / NM_001164342.2; = p.V553= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV100615380; called by muse, mutect2, varscan2
- ZNF365 | c.1173C>T p.I391= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV101238001; called by muse, mutect2
- ZNF407 | c.4752C>T p.N1584= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV99996900; called by muse, mutect2, varscan2
- ZNF99 | c.2265T>C p.H755= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101233988; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852089 G>A | 3'Flank (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- CABP1 | c.655-3741C>T | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs201055119; called by mutect2, varscan2
- MICAL3 | c.2241+4670G>A | Intron (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99263043; called by muse, mutect2
- MIR551B | n.38G>A | RNA (SNP) | VAF 16/193 reads (8%) | called by muse, mutect2
- OR2W5 | n.753C>T | RNA (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- PDE4A | c.784-1513G>T | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99535309; called by muse, mutect2, varscan2
- XIST | n.8832T>C | RNA (SNP) | VAF 10/30 reads (33%) | called by mutect2, varscan2
